Somatic mutation profile of tumor specimen MP2PRT-PARUGP-TMP1-A (aliquot MP2PRT-PARUGP-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PARUGP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (759 days).
Specimen MP2PRT-PARUGP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2172751d-a882-4fae-95cd-eca4515dec3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUGP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUGP-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22ddc11a-eeae-47b9-b836-c38bdc637260

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 38/467 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 205/317 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKMY1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs751138075; called by muse, mutect2, varscan2
- NUMA1 | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 159/429 reads (37%) | catalogued as COSV61185624; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1183C>T p.R395W (on ENST00000352766; = p.R316W on NM_181334.5) | Missense Mutation (SNP) | VAF 148/498 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs1322026918; called by muse, mutect2, varscan2
- DPYSL3 | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ADGRL1 | c.120G>A p.A40= | Silent (SNP) | VAF 190/499 reads (38%) | catalogued as rs780125002; called by muse, mutect2, varscan2
- ARRB1 | c.1041G>T p.L347= | Silent (SNP) | VAF 93/335 reads (28%) | catalogued as rs778065479; called by muse, mutect2, varscan2
- PTPRO | c.2415G>A p.T805= | Silent (SNP) | VAF 86/181 reads (48%) | catalogued as rs147165417; called by muse, mutect2, varscan2
- SALL3 | c.1497C>T p.Y499= | Silent (SNP) | VAF 33/1039 reads (3%) | catalogued as rs1477108765, COSV73306016; called by muse, mutect2
- TECTA | c.3783G>A p.S1261= | Silent (SNP) | VAF 144/363 reads (40%) | catalogued as rs1424229038; called by muse, mutect2, varscan2
- RUNX1T1 | c.-86+4497C>A | Intron (SNP) | VAF 254/455 reads (56%) | called by muse, mutect2, varscan2
